Somatic mutation profile of cancer-model specimen HCM-CSHL-0184-C25-85A (3D Organoid; aliquot HCM-CSHL-0184-C25-85A-01D-A78L-36), derived from the primary tumor of HCMI case HCM-CSHL-0184-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 77.3 years (28,240 days).
Specimen HCM-CSHL-0184-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2cec1b1-11da-43e0-be7a-86f8651740b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0184-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0184-C25-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79f27ad8-582c-4716-9af6-dabfc3fe49f5

The open-access MAF lists 61 somatic variants for this specimen: 43 protein-altering or splice-affecting, 10 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 10, Intron 3, Nonsense Mutation 2, 3'Flank 2, Frame Shift Del 2, 3'UTR 1, In Frame Del 1, 5'Flank 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 254/536 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PANK3 | c.901A>T p.I301F | Missense Mutation (SNP) | VAF 16/119 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs77612793; called by muse, mutect2, varscan2
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 192/192 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AKAP6 | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 137/459 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757242670; called by muse, mutect2, varscan2
- ANKS1A | c.2170G>A p.D724N | Missense Mutation (SNP) | VAF 21/262 reads (8%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.993); catalogued as rs1257206556, COSV64462125; called by muse, mutect2
- APC | c.5369G>A p.R1790K | Missense Mutation (SNP) | VAF 46/199 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1158503665, COSV57328312; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTRC | c.860G>A p.R287K (on ENST00000370187 / NM_033637.4; = p.R251K on NM_003939.5) | Missense Mutation (SNP) | VAF 27/27 reads (100%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.965); catalogued as COSV64579603; called by muse, mutect2, varscan2
- CA10 | c.522G>T p.K174N | Missense Mutation (SNP) | VAF 15/287 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.524); catalogued as COSV99563478; called by muse, mutect2
- CYP2R1 | c.172T>G p.S58A | Missense Mutation (SNP) | VAF 113/115 reads (98%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as rs782622230; called by muse, mutect2, varscan2
- EGFR | c.2230A>G p.I744V | Missense Mutation (SNP) | VAF 306/501 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as rs1554348865, COSV104369002, COSV51766284; called by muse, mutect2, varscan2
- FLRT2 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 84/234 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs745818091, COSV58145614; called by muse, varscan2
- GRB14 | c.1351C>T p.R451* | Nonsense Mutation (SNP) | VAF 65/139 reads (47%) | catalogued as rs1457587748; called by muse, mutect2, varscan2
- KCNH2 | c.3049G>A p.A1017T | Missense Mutation (SNP) | VAF 96/97 reads (99%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs950543448, CD139906; called by muse, mutect2, varscan2
- KCTD9 | c.326A>C p.N109T | Missense Mutation (SNP) | VAF 63/63 reads (100%) | SIFT tolerated (0.74); PolyPhen benign (0.039); catalogued as rs778794171; called by muse, mutect2, varscan2
- MUC16 | c.37207G>A p.E12403K | Missense Mutation (SNP) | VAF 83/206 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.042); catalogued as rs1407929387, COSV67448438; called by muse, mutect2, varscan2
- SSU72 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 273/273 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as rs1023230253; called by muse, mutect2, varscan2
- STON1 | c.1447C>T p.L483F | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.983); catalogued as rs1258701725, COSV59128687; called by muse, mutect2
- TRIM37 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 113/245 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs1480459291; called by muse, mutect2, varscan2
- WDR47 | c.1304G>A p.R435H (on ENST00000369962 / NM_001142551.2; = p.R436H on NM_014969.5) | Missense Mutation (SNP) | VAF 114/216 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs760204418, COSV100728346; called by muse, mutect2, varscan2
- ZNF311 | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 110/240 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as rs765712189, COSV101014142, COSV65853519; called by muse, mutect2, varscan2
- ZNF592 | c.3695C>T p.A1232V | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.015); catalogued as rs201671775; called by muse, mutect2, varscan2
- CTH | c.298C>T p.L100F | Missense Mutation (SNP) | VAF 218/649 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- DIO1 | c.465A>C p.E155D | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- DOCK2 | c.1912A>G p.K638E | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FMR1 | c.1564A>G p.R522G | Missense Mutation (SNP) | VAF 70/139 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- GFI1 | c.794C>G p.S265C | Missense Mutation (SNP) | VAF 314/501 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- GRXCR2 | c.208G>T p.V70F | Missense Mutation (SNP) | VAF 66/269 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- GSTO2 | c.293C>A p.P98Q | Missense Mutation (SNP) | VAF 154/154 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IPO4 | c.1895del p.F632Sfs*54 | Frame Shift Del (DEL) | VAF 131/281 reads (47%) | called by mutect2, pindel, varscan2
- KIF23 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 76/260 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCKAP5L | c.1105C>G p.Q369E | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.519); called by muse, mutect2
- PLEC | c.13537_13578del p.K4513_E4526del (on ENST00000322810 / NM_201380.4; = p.K4403_E4416del on NM_000445.5) | In Frame Del (DEL) | VAF 46/321 reads (14%) | called by mutect2, pindel
- PPL | c.689A>T p.D230V | Missense Mutation (SNP) | VAF 68/215 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- PPP2R1B | c.1684A>T p.I562F | Missense Mutation (SNP) | VAF 96/162 reads (59%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCUBE2 | c.2154G>A p.W718* (on ENST00000649792 / NM_001367977.2; = p.W563* on NM_001170690.2) | Nonsense Mutation (SNP) | VAF 61/61 reads (100%) | called by muse, mutect2, varscan2
- SLC12A4 | c.670T>G p.L224V | Missense Mutation (SNP) | VAF 116/193 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- TBC1D8B | c.2821C>A p.P941T | Missense Mutation (SNP) | VAF 74/203 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TMEM221 | c.164C>A p.A55D | Missense Mutation (SNP) | VAF 72/110 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- WASL | c.491T>C p.I164T | Missense Mutation (SNP) | VAF 59/59 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- XKR3 | c.1066G>T p.V356L | Missense Mutation (SNP) | VAF 11/277 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2
- ZFHX4 | c.6640T>C p.S2214P | Missense Mutation (SNP) | VAF 105/217 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ZNF285 | c.-41C>T | Splice Region (SNP) | VAF 86/204 reads (42%) | called by muse, mutect2, varscan2
- ZNRF1 | c.667del p.E223Nfs*35 | Frame Shift Del (DEL) | VAF 123/494 reads (25%) | called by mutect2, pindel, varscan2
- DESI2 | c.138T>G p.P46= | Silent (SNP) | VAF 81/255 reads (32%) | called by muse, mutect2, varscan2
- DNAAF4 | c.1086T>C p.A362= | Silent (SNP) | VAF 45/183 reads (25%) | called by muse, mutect2, varscan2
- FLG2 | c.843T>A p.G281= | Silent (SNP) | VAF 100/181 reads (55%) | catalogued as COSV101165709; called by muse, mutect2, varscan2
- H1-2 | c.252C>T p.L84= | Silent (SNP) | VAF 180/331 reads (54%) | catalogued as rs1224166339, COSV59191386; called by muse, mutect2, varscan2
- MAN2A1 | c.1806T>C p.S602= | Silent (SNP) | VAF 112/158 reads (71%) | called by muse, mutect2, varscan2
- MUC16 | c.39420T>C p.P13140= | Silent (SNP) | VAF 39/304 reads (13%) | called by muse, mutect2, varscan2
- SERPINB2 | c.696A>G p.V232= | Silent (SNP) | VAF 24/24 reads (100%) | called by muse, varscan2
- SIGLEC11 | c.1902G>A p.P634= | Silent (SNP) | VAF 75/163 reads (46%) | catalogued as rs185965511, COSV68567514; called by muse, mutect2, varscan2
- TSHZ2 | c.1830G>A p.A610= | Silent (SNP) | VAF 152/152 reads (100%) | catalogued as rs147016688, COSV61587419; called by muse, mutect2, varscan2
- ZIC3 | c.252C>A p.A84= | Silent (SNP) | VAF 106/222 reads (48%) | called by muse, mutect2, varscan2
- AOAH | c.1600-1162G>T | Intron (SNP) | VAF 163/336 reads (49%) | called by muse, mutect2, varscan2
- CTSA | c.195-35C>T | Intron (SNP) | VAF 28/333 reads (8%) | called by muse, mutect2
- CTTN | c.679+10G>A | Intron (SNP) | VAF 74/148 reads (50%) | catalogued as rs764505525; called by muse, mutect2, varscan2
- GLB1L2 | c.-44G>A | 5'UTR (SNP) | VAF 124/249 reads (50%) | called by muse, mutect2, varscan2
- JARID2 | c.*600G>C | 3'UTR (SNP) | VAF 8/174 reads (5%) | called by muse, mutect2
- MUC19 | chr12:40545336 T>A | 3'Flank (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- PRDM11 | chr11:45227998 A>C | 3'Flank (SNP) | VAF 7/122 reads (6%) | called by muse, mutect2
- PTPA | chr9:129110981 C>T | 5'Flank (SNP) | VAF 139/254 reads (55%) | catalogued as rs113217898; called by muse, mutect2, varscan2
